Surgical pathology report (de-identified scan), TCGA case TCGA-AY-A54L, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-A54L-01A (Primary Tumor).

[page 1 of 3]
Diagnosis:

A: Colon, right, resection

Tumor Histologic Type: Invasive colonic adenocarcinoma (see comment)

Histologic Grade: Low grade, grade 2 of 4 (moderately differentiated)

Tumor Size: 3.4 cm in diameter

Tumor Location: Right colon

Depth of Invasion: To junction between muscularis propria and subserosal soft tissues; no definite extension beyond muscularis propria identified (SMA immunostain performed)

Lymphovascular Invasion: Not identified

Perineural Invasion: Not identified

Margins:

Proximal margin: Negative, 16 cm away

Distal margin: Negative, 8.1 cm away

Mesenteric margin: Negative, 5.4 cm away

Regional Lymph Nodes:

Total number with metastases: 0

Total number examined: 24

IHC for Mismatch Repair Protein Expression:

MLH1: Normal expression

PMS2: Normal expression

MSH2: Normal expression

MSH6: Normal expression

Additional Pathologic Findings: Submucosal lipoma;
Fibrous obliteration of distal appendiceal lumen;
Separately submitted omentum with no involvement by carcinoma identified

AJCC Pathologic TNM Stage: pT2 pN0

ICDD-3

Adenocarcinoma, NOS

8/40/3

Site: Path R Colon C18.2

C6CF Hepatic flexure C18.2

9w 12/3/12

[page 2 of 3]
Note: This pathologic stage assessment is based on information available at the time of this report and is subject to change pending clinical review and additional information.

Comment:

Materials will be submitted to the _____ for microsatellite instability testing. These results will be issued in a separate _____ report.

Clinical History:

with colon cancer.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right colon and omentum." It consists of a 2.9 cm long x 1.6 cm in circumference terminal ileum contiguous with a 26.8 cm long x 6.0 cm in circumference large bowel with attached vermiform appendix (4.7 cm long x 0.5 cm in diameter), omentum (13.9 x 4.7 x 1.3 cm), and pericolic fat extending the length of the specimen up to 3.6 cm thick.

There is a 3.4 x 2.7 x 0.7 cm firm gray/tan mass with raised borders that is 16.7 cm from the proximal margin and 8.1 cm from the distal margin. The mass extends 0.3 cm into the muscularis propria but not through it, 0.6 cm from the serosa (inked black), and 5.4 cm from the mesenteric margin (inked red).

Proximal to the mass by 7.7 cm is a 1.0 x 0.7 x 0.4 cm submucosal fatty nodule that is 7.3 cm from the ileocecal valve. The appendix is unremarkable.

Also received in the same container is a 31.4 x 11.5 x 2.2 cm focally red/brown

[page 3 of 3]
segment of lobulated adipose tissue consistent with omental tissue. The pericolic adipose tissue is dissected for lymph node candidates of which 21 are identified, ranging from 0.2 cm in greatest dimension up to 0.8 x 0.8 x 0.7 cm. The lymph nodes are firm and white.

Tumor and normal are given to

Block Summary:

A1 - proximal margin, en face
A2 - distal margin, en face
A3 - mesenteric margin, en face
A4-A7 - mass, deepest extension
A8 - submucosal fatty nodule
A9 - appendix
A10 - separate segment of omentum
A11-A13 - each contains five lymph node candidates
A14-A16 - each contains two lymph node candidates, bisected, one is inked
black

HPA Discrepancy		

11/26/12

Source: NCI Genomic Data Commons file 97a8b1db-458e-4d03-9a78-14ea33af7cd4 (TCGA-AY-A54L.5319D80A-3DFD-4834-A905-D34E668D4A2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).